Somatic mutation profile of tumor specimen TCGA-O2-A52W-01A (aliquot TCGA-O2-A52W-01A-11D-A26M-08) from TCGA case TCGA-O2-A52W, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 63.4 years (23,156 days).
Specimen TCGA-O2-A52W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8423fcd7-a969-44ca-a999-31bd16df4c49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O2-A52W-10A (Blood Derived Normal), aliquot TCGA-O2-A52W-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3f3a112-05ae-4536-9516-adee7e345b40

The open-access MAF lists 132 somatic variants for this specimen: 100 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 29, In Frame Del 11, Frame Shift Del 9, Nonsense Mutation 8, Splice Site 6, Intron 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNB | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777259, CM143666, COSV99914738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4348-1G>C p.X1450_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100623035; called by muse, mutect2, varscan2
- ADCK5 | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100450698; called by muse, mutect2, varscan2
- ADCY2 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57890528, COSV57906803; called by muse, mutect2, varscan2
- ADCY8 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99654198; called by muse, mutect2
- ADGRL4 | c.1462-2A>G p.X488_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100876536; called by muse, mutect2, varscan2
- APOB | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99267925; called by muse, mutect2, varscan2
- ASTN1 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV56061735, COSV99922973; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99314489; called by muse, mutect2, varscan2
- BEND7 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV100347026; called by muse, mutect2, varscan2
- CAPSL | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368551299, COSV68438743; called by muse, mutect2, varscan2
- CCDC112 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs151110926; called by muse, mutect2, varscan2
- COL16A1 | c.3418C>T p.R1140* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as rs770009606, COSV99594614; called by muse, mutect2, varscan2
- CPS1 | c.3206A>T p.Y1069F | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV99244038; called by muse, mutect2
- CROT | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100519424, COSV100519678; called by muse, mutect2, varscan2
- DDI2 | c.633-2A>C p.X211_splice | Splice Site (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100197881; called by muse, mutect2, varscan2
- EFHB | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs762327494, COSV99860202; called by muse, mutect2, varscan2
- EQTN | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.097); catalogued as COSV101192404; called by muse, mutect2, varscan2
- FDCSP | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.457); catalogued as rs775215113, COSV100525765; called by muse, mutect2, varscan2
- FILIP1 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369386052, COSV52741820; called by muse, mutect2, varscan2
- FRAS1 | c.4862G>C p.R1621T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99355688; called by muse, mutect2, varscan2
- FSCB | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as rs774752286, COSV100469844; called by muse, mutect2, varscan2
- GAPDH | c.768_770del p.D257del | In Frame Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs779337992; called by pindel, varscan2
- GPI | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1435398228, CM970694, COSV100731577; called by muse, mutect2, varscan2
- GPR174 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV99338368; called by muse, mutect2, varscan2
- GTF3C1 | c.4780G>A p.D1594N | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649691; called by muse, mutect2
- HTR1E | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766560806, COSV100540916, COSV59507323; called by muse, mutect2, varscan2
- IGDCC4 | c.1505A>T p.Y502F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.349); catalogued as COSV100733130; called by muse, mutect2
- KIAA1614 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs988009643, COSV100851354, COSV62554039; called by muse, mutect2, varscan2
- KIF1C | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.7); PolyPhen possibly damaging (0.899); catalogued as COSV100297294, COSV57903033; called by muse, mutect2, varscan2
- KIR3DL2 | c.89del p.F30Sfs*56 | Frame Shift Del (DEL) | VAF 42/189 reads (22%) | catalogued as COSV99551853; called by mutect2, pindel, varscan2
- KMT2D | c.10057C>T p.Q3353* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99985604; called by muse, mutect2
- KMT2D | c.9151G>T p.A3051S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56419732, COSV99985606; called by muse, mutect2, varscan2
- LIG3 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770579198, COSV52007408; called by mutect2, varscan2
- LINGO3 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101347284, COSV68261401; called by muse, mutect2, varscan2
- LRRFIP1 | c.505G>T p.E169* (on ENST00000392000 / NM_001137552.2; = p.E145* on NM_004735.4) | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99791249; called by muse, mutect2, varscan2
- MAGEC1 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.213); catalogued as COSV99596484; called by muse, mutect2, varscan2
- MED12 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV61354946; called by muse, mutect2, varscan2
- MSH3 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99435637; called by muse, mutect2, varscan2
- MYO5A | c.1791G>T p.K597N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV100698141; called by muse, mutect2
- NBPF20 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 44/426 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.785); catalogued as rs1553665945; called by muse, mutect2
- NEFM | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as rs1201317257, COSV55331529; called by mutect2, varscan2
- NEUROD4 | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV99670139; called by muse, mutect2, varscan2
- NIPAL2 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100358729; called by muse, mutect2, varscan2
- OPA1 | c.790-1G>T p.X264_splice (on ENST00000361510 / NM_130837.3; = p.X209_splice on NM_015560.3) | Splice Site (SNP) | VAF 14/96 reads (15%) | catalogued as COSV62479820; called by muse, mutect2, varscan2
- OR2Z1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV60691992; called by muse, mutect2, varscan2
- OR4A5 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV100157295; called by muse, mutect2, varscan2
- OR4L1 | c.694G>C p.G232R | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as COSV100235905; called by muse, mutect2, varscan2
- OR9A4 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71885958, COSV71886030; called by muse, mutect2, varscan2
- OVGP1 | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100868267; called by muse, mutect2, varscan2
- PANK4 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101022556; called by muse, mutect2, varscan2
- PAPOLA | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as COSV99354618; called by muse, mutect2, varscan2
- PCDHB6 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554277556, COSV99171194; called by muse, mutect2, varscan2
- PDZD2 | c.2999A>G p.D1000G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV99226623; called by muse, mutect2, varscan2
- PRKAG1 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100305441; called by muse, mutect2, varscan2
- RHOBTB3 | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.074); catalogued as COSV101183258; called by muse, varscan2
- RNF213 | c.6088G>A p.V2030M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1342374812, COSV100301453; called by muse, mutect2, varscan2
- RPAP3 | c.667+1G>T p.X223_splice | Splice Site (SNP) | VAF 17/80 reads (21%) | catalogued as COSV99139548; called by muse, mutect2, varscan2
- RPS6KA3 | c.1784A>G p.Y595C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101084654; called by muse, mutect2, varscan2
- SCN7A | c.4812G>T p.L1604F | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV101313362; called by muse, mutect2, varscan2
- SH3TC1 | c.2747C>T p.A916V | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs773689900, COSV55287408; called by muse, mutect2, varscan2
- SHANK1 | c.1747G>T p.V583L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99521999; called by muse, mutect2
- SLC17A9 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV64848699; called by muse, mutect2, varscan2
- SLC18B1 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV99259335; called by muse, mutect2, varscan2
- SLC26A5 | c.1496_1497del p.V499Dfs*17 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1331611808; called by pindel, varscan2
- SMARCB1 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99575729; called by muse, mutect2, varscan2
- SMPDL3A | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100868734; called by muse, mutect2, varscan2
- SSH1 | c.1482_1484del p.F494del | In Frame Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs748461008; called by pindel, varscan2
- SYNE2 | c.3164C>T p.T1055I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1465426572, COSV100648460; called by muse, mutect2
- TAF3 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 7/139 reads (5%) | catalogued as COSV60208044; called by muse, mutect2
- TBC1D32 | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776659632, COSV51540912, COSV99251230; called by muse, mutect2, varscan2
- TMEM273 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100939691, COSV100939734; called by muse, mutect2, varscan2
- TRIP12 | c.4972A>G p.S1658G | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99390912; called by muse, mutect2, varscan2
- UGT1A10 | c.229T>A p.Y77N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs759958389, COSV100762470; called by muse, mutect2, varscan2
- ULK2 | c.2983G>C p.A995P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860968; called by muse, mutect2, varscan2
- UNC5C | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs376193832; called by muse, mutect2
- USH2A | c.2732C>A p.T911N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as rs397518006, CM044726, COSV56358921; ClinVar: likely benign; called by muse, mutect2, varscan2
- VWA3B | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV101346165; called by muse, mutect2, varscan2
- VWA3B | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV101346166; called by muse, mutect2, varscan2
- WASHC4 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV100162761; called by muse, mutect2, varscan2
- WNT9B | c.989_991del p.S330del | In Frame Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs757334174; called by mutect2, pindel, varscan2
- ZNF831 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100926247; called by muse, mutect2, varscan2
- ZZEF1 | c.7828G>T p.V2610L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV101068061; called by muse, mutect2, varscan2
- ARAP3 | c.3093_3117del p.A1032Gfs*8 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel
- CBLB | c.1686_1688del p.P564del | In Frame Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- CENPS | c.348_349del p.K117Vfs*20 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- COL26A1 | c.856+3_856+6del p.X286_splice (on ENST00000313669 / NM_001278563.3; = p.X284_splice on NM_133457.4) | Splice Site (DEL) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- DLAT | c.1490_1492del p.S497del | In Frame Del (DEL) | VAF 14/42 reads (33%) | called by pindel, varscan2
- EIF2S2 | c.891_892del p.Y298Ffs*10 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by pindel, varscan2
- FNTA | c.497_498del p.Y166Sfs*6 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- JAK1 | c.921_923del p.G308del | In Frame Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- LRRC32 | c.1924_1926del p.L642del | In Frame Del (DEL) | VAF 16/104 reads (15%) | called by pindel, varscan2
- NPFFR1 | c.90_102del p.F32Ifs*83 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, varscan2*
- PKDREJ | c.3904_3906del p.N1302del | In Frame Del (DEL) | VAF 26/138 reads (19%) | called by pindel, varscan2
- PLXNB2 | c.3856_3858del p.F1286del | In Frame Del (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2
- RACK1 | c.342_344del p.S115del | In Frame Del (DEL) | VAF 10/56 reads (18%) | called by pindel, varscan2
- RAI1 | c.4254_4255del p.S1419Ffs*3 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- SBF2 | c.2903_2905del p.E968del | In Frame Del (DEL) | VAF 26/93 reads (28%) | called by pindel, varscan2
- TAGLN2 | c.341_342del p.V114Gfs*27 | Frame Shift Del (DEL) | VAF 13/131 reads (10%) | called by pindel, varscan2
- ABLIM2 | c.1185G>A p.R395= (on ENST00000341937 / NM_001130084.2; = p.R428= on NM_001130083.2) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs778496423, COSV99590466; called by muse, mutect2, varscan2
- ANGPTL4 | c.882T>A p.G294= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100035258; called by muse, mutect2, varscan2
- ART3 | c.378A>T p.R126= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100587966; called by muse, mutect2, varscan2
- ATRN | c.2349G>A p.L783= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1366297692, COSV99497803; called by muse, mutect2, varscan2
- CTNNA2 | c.1614G>A p.R538= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100561991, COSV58169057; called by muse, mutect2, varscan2
- DNAH5 | c.573C>T p.D191= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as rs773770450, COSV99453973; ClinVar: likely benign; called by muse, mutect2, varscan2
- DRP2 | c.885G>C p.L295= | Silent (SNP) | VAF 66/153 reads (43%) | catalogued as COSV100872061; called by muse, mutect2, varscan2
- FAM135B | c.2970C>G p.T990= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV99425406, COSV99427374; called by muse, mutect2, varscan2
- HCFC2 | c.1428T>C p.N476= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1484667869, COSV99983275; called by muse, mutect2, varscan2
- IGSF21 | c.753C>A p.T251= | Silent (SNP) | VAF 53/207 reads (26%) | catalogued as COSV99246121; called by muse, mutect2, varscan2
- INHBC | c.228G>A p.L76= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100548052; called by muse, mutect2, varscan2
- KIF2B | c.1044G>T p.L348= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV99276181; called by muse, mutect2, varscan2
- KMT2D | c.9150G>T p.L3050= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99985607; called by muse, mutect2, varscan2
- LAG3 | c.828C>T p.S276= | Silent (SNP) | VAF 19/221 reads (9%) | catalogued as COSV52568235; called by muse, mutect2
- NOM1 | c.1452C>T p.F484= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs760370842, COSV51981603; called by muse, mutect2, varscan2
- OCA2 | c.2484C>G p.L828= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV62339867; called by muse, varscan2
- OR2J3 | c.663T>C p.Y221= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1397467847, COSV101013643, COSV101013662; called by muse, mutect2, varscan2
- PANK2 | c.1518A>G p.R506= (on ENST00000316562 / NM_153638.3; = p.R215= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100262501; called by muse, mutect2, varscan2
- PPFIBP2 | c.1830G>A p.K610= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV55077117; called by muse, mutect2, varscan2
- RHOBTB3 | c.1242T>C p.L414= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV101183260; called by muse, varscan2
- SERPINB10 | c.300C>T p.L100= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SPATA31D1 | c.2130G>T p.L710= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100783046; called by muse, mutect2, varscan2
- SRSF4 | c.345C>T p.C115= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100861435; called by muse, mutect2, varscan2
- TBC1D32 | c.2652G>T p.R884= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99251228; called by muse, mutect2, varscan2
- TMEM79 | c.462C>A p.G154= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99828113; called by muse, mutect2, varscan2
- XKR3 | c.774A>T p.A258= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- ZNF141 | c.1146G>T p.L382= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99549999; called by muse, mutect2, varscan2
- ZNF224 | c.1458T>C p.C486= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100425522; called by muse, mutect2, varscan2
- ZNF521 | c.507C>A p.T169= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs370530167, COSV100833349; called by muse, mutect2, varscan2
- KIF1B | c.2115+6851_2115+6852del | Intron (DEL) | VAF 30/141 reads (21%) | called by pindel, varscan2
- MIR1270 | chr19:20397810 C>T | 3'Flank (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- ZNF99 | c.*1042G>T | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as COSV68055930; called by muse, mutect2, varscan2
